Somatic mutation profile of tumor specimen ALCH-B1OR-TTR1-A (aliquot ALCH-B1OR-TTR1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B1OR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.6 years (29,803 days).
Specimen ALCH-B1OR-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b0175be-8e77-49f0-bd49-84c9d31a2bdb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1OR-NB1-A (Blood Derived Normal), aliquot ALCH-B1OR-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f434c07-d5a7-4c3b-b60e-987c9628a1a9

The open-access MAF lists 234 somatic variants for this specimen: 169 protein-altering or splice-affecting, 37 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 37, Intron 15, Nonsense Mutation 11, Frame Shift Del 6, 3'UTR 5, 5'UTR 4, Splice Region 3, Splice Site 3, 3'Flank 3, Frame Shift Ins 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUBN | c.673T>A p.C225S | Missense Mutation (SNP) | VAF 282/2466 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs386833790, CM127837; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 490/920 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.863-2A>T p.X288_splice | Splice Site (SNP) | VAF 135/238 reads (57%) | hotspot (GDC flag); catalogued as CD055731, CS132644, COSV58829315, COSV58830079; called by muse, mutect2, varscan2
- ACTN3 | c.1892C>A p.T631K | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.145); catalogued as COSV59748085; called by muse, mutect2, varscan2
- ADCY1 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs369079165, COSV52030947; called by muse, mutect2, varscan2
- ADGRE5 | c.2200A>G p.K734E (on ENST00000242786 / NM_078481.4; = p.K641E on NM_001784.5) | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs1161706924; called by muse, mutect2, varscan2
- ADGRE5 | c.2201A>C p.K734T (on ENST00000242786 / NM_078481.4; = p.K641T on NM_001784.5) | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs1410010910; called by muse, mutect2, varscan2
- AHNAK | c.2344G>T p.G782W | Missense Mutation (SNP) | VAF 404/796 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99061814; called by muse, mutect2, varscan2
- AHNAK2 | c.13235G>A p.G4412D | Missense Mutation (SNP) | VAF 76/251 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as rs764108680, COSV60917952; called by muse, mutect2, varscan2
- AHNAK2 | c.8246C>G p.P2749R | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs766276103; called by muse, mutect2, varscan2
- AK4 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs142956995; called by muse, mutect2, varscan2
- CACNG1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 70/498 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs550820114; called by muse, mutect2, varscan2
- CDH24 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 146/406 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319429784; called by muse, mutect2, varscan2
- CFAP74 | c.4233C>T p.V1411= | Splice Region (SNP) | VAF 11/34 reads (32%) | catalogued as rs1299700901; called by muse, mutect2, varscan2
- CILP2 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 121/644 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757408856; called by muse, mutect2, varscan2
- CLRN3 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 140/256 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150481499; called by muse, mutect2, varscan2
- COL5A2 | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 241/1722 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV66408152; called by muse, mutect2, varscan2
- CYP3A4 | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 198/1125 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs751246524; called by muse, mutect2, varscan2
- DHTKD1 | c.2497A>G p.I833V | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as rs972227565; called by muse, mutect2, varscan2
- FKBP5 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 83/689 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61880949; called by muse, mutect2, varscan2
- GRIK4 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101483546; called by muse, mutect2, varscan2
- H3C11 | c.106G>C p.V36L | Missense Mutation (SNP) | VAF 35/295 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV58900970; called by muse, mutect2, varscan2
- HSF1 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 55/416 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.077); catalogued as COSV100184041; called by muse, mutect2, varscan2
- KCNH7 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 142/1385 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs771751716, COSV59817658; called by muse, mutect2, varscan2
- LACC1 | c.699del p.N234Mfs*13 | Frame Shift Del (DEL) | VAF 93/272 reads (34%) | catalogued as COSV57829063, COSV57829724; called by mutect2, pindel, varscan2
- LGALS3BP | c.107G>C p.R36P | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749155942, COSV53164422; called by muse, mutect2, varscan2
- LYST | c.8299A>G p.I2767V | Missense Mutation (SNP) | VAF 192/1730 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as rs1206454517; called by muse, mutect2, varscan2
- MEX3B | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs978594058, COSV100314163; called by muse, mutect2, varscan2
- MMRN1 | c.1092C>A p.S364R | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs537246177, COSV53335138, COSV53342865; called by muse, mutect2, varscan2
- MUC2 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 58/269 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs752323302; called by muse, mutect2, varscan2
- MYH1 | c.2975C>A p.T992N | Missense Mutation (SNP) | VAF 434/1062 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs563867561; called by muse, mutect2, varscan2
- NGRN | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs1345541278; called by muse, mutect2, varscan2
- NKX2-4 | c.750C>A p.D250E | Missense Mutation (SNP) | VAF 145/835 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.159); catalogued as rs767132536; called by muse, mutect2, varscan2
- NMD3 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 128/365 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1352550282; called by muse, mutect2, varscan2
- OPRM1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 126/560 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200251590; called by muse, mutect2, varscan2
- PCDHA12 | c.1936C>A p.R646S | Missense Mutation (SNP) | VAF 190/536 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.249); catalogued as COSV56505834; called by muse, mutect2, varscan2
- PCDHB12 | c.1566G>T p.E522D | Missense Mutation (SNP) | VAF 210/1068 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99507250; called by muse, varscan2
- PCDHGA11 | c.1570G>T p.E524* | Nonsense Mutation (SNP) | VAF 86/241 reads (36%) | catalogued as COSV99548095; called by muse, mutect2, varscan2
- PCDHGA12 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 179/451 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.022); catalogued as rs1561849765; called by muse, mutect2, varscan2
- PCDHGA3 | c.615dup p.E206Rfs*11 | Frame Shift Ins (INS) | VAF 53/316 reads (17%) | catalogued as rs766211480; called by mutect2, pindel, varscan2
- PHRF1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 68/282 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1198667569, COSV99199890; called by muse, mutect2, varscan2
- PSD2 | c.1617G>T p.W539C | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51210846; called by muse, mutect2, varscan2
- PTK7 | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 93/345 reads (27%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.626); catalogued as rs1460965413; called by muse, mutect2, varscan2
- REG3A | c.36G>C p.W12C | Missense Mutation (SNP) | VAF 80/557 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59408322; called by muse, mutect2, varscan2
- RPTN | c.1776A>T p.Q592H | Missense Mutation (SNP) | VAF 338/2861 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV60166225; called by muse, mutect2, varscan2
- RTP5 | c.1553G>T p.R518L | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.225); catalogued as rs781309657, COSV58319053; called by muse, mutect2, varscan2
- SIRPD | c.5C>A p.P2H | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV101064866; called by muse, mutect2, varscan2
- SLC5A1 | c.749C>A p.T250N | Missense Mutation (SNP) | VAF 209/896 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.17); catalogued as COSV99833337; called by muse, mutect2, varscan2
- SOX17 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 121/185 reads (65%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV52026094; called by muse, mutect2, varscan2
- SPTBN4 | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 104/673 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100150257; called by muse, mutect2, varscan2
- SRD5A2 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 143/806 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs973116318; called by muse, mutect2, varscan2
- STAB2 | c.3589G>A p.D1197N | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.146); catalogued as rs1450064026, COSV101185952; called by muse, mutect2
- UNC79 | c.2533G>T p.G845* (on ENST00000393151 / NM_001346218.2; = p.G668* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 82/330 reads (25%) | catalogued as COSV56388054; called by mutect2, varscan2
- USP29 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54142884, COSV54147687; called by muse, mutect2, varscan2
- WIPF1 | c.454G>C p.V152L | Missense Mutation (SNP) | VAF 99/687 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV55815322; called by muse, mutect2, varscan2
- ZFP57 | c.566A>T p.Y189F | Missense Mutation (SNP) | VAF 163/297 reads (55%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as COSV65305982; called by muse, mutect2, varscan2
- ZNF441 | c.1115C>A p.A372D | Missense Mutation (SNP) | VAF 162/388 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); catalogued as rs558868530, COSV63540439; called by muse, mutect2, varscan2
- AARS1 | c.790G>T p.V264F | Missense Mutation (SNP) | VAF 172/824 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- ACAN | c.4873del p.L1625Ffs*37 | Frame Shift Del (DEL) | VAF 434/1040 reads (42%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.887T>A p.V296E | Missense Mutation (SNP) | VAF 389/1202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRL4 | c.1402T>A p.C468S | Missense Mutation (SNP) | VAF 73/308 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ALDH16A1 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- ALDH3B2 | c.60G>A p.W20* | Nonsense Mutation (SNP) | VAF 50/253 reads (20%) | called by muse, mutect2, varscan2
- ANHX | c.275A>T p.Q92L | Missense Mutation (SNP) | VAF 137/341 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK1 | c.4503C>A p.D1501E | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD30B | c.1825+1G>T p.X609_splice | Splice Site (SNP) | VAF 29/132 reads (22%) | called by muse, mutect2, varscan2
- ASPM | c.9320G>T p.R3107L | Missense Mutation (SNP) | VAF 148/852 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- ATM | c.9167T>A p.V3056E | Missense Mutation (SNP) | VAF 131/316 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- AZGP1 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 316/610 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- BACH2 | c.2211C>G p.D737E | Missense Mutation (SNP) | VAF 71/360 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BVES | c.253A>G p.T85A | Missense Mutation (SNP) | VAF 80/350 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, varscan2
- C5orf22 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEL | c.797A>T p.K266M (on ENST00000673714; = p.K263M on NM_001807.6) | Missense Mutation (SNP) | VAF 122/513 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CGB1 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CLCA2 | c.2764G>T p.V922L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLTCL1 | c.3978A>T p.K1326N | Missense Mutation (SNP) | VAF 51/360 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTN1 | c.3053T>A p.F1018Y | Missense Mutation (SNP) | VAF 175/1566 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CNTNAP3 | c.2879G>T p.G960V | Missense Mutation (SNP) | VAF 95/881 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- CR1L | c.1409G>C p.C470S | Missense Mutation (SNP) | VAF 75/651 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CRYBG1 | c.2617T>C p.S873P | Missense Mutation (SNP) | VAF 95/413 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CWF19L2 | c.2665A>T p.T889S | Missense Mutation (SNP) | VAF 72/133 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CYBRD1 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 58/363 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- DGKZ | c.544G>T p.G182C | Missense Mutation (SNP) | VAF 76/400 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNM1 | c.1984A>C p.I662L | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DPEP1 | c.697T>C p.F233L | Missense Mutation (SNP) | VAF 79/307 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- DYNC1H1 | c.11583G>C p.K3861N | Missense Mutation (SNP) | VAF 79/288 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DYNC1LI1 | c.1572A>T p.*524Cext*15 | Nonstop Mutation (SNP) | VAF 48/217 reads (22%) | called by muse, mutect2, varscan2
- EEF1A1 | c.1128G>T p.K376N | Missense Mutation (SNP) | VAF 62/854 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.03); called by muse, mutect2
- EEF1A2 | c.1356del p.K453Sfs*? | Frame Shift Del (DEL) | VAF 51/145 reads (35%) | called by mutect2, pindel, varscan2
- FAM160A2 | c.1382G>A p.C461Y | Missense Mutation (SNP) | VAF 101/444 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM81B | c.771G>T p.K257N | Missense Mutation (SNP) | VAF 99/371 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.919); called by muse, varscan2
- FAM83C | c.1460C>A p.T487K | Missense Mutation (SNP) | VAF 176/399 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT2 | c.11613G>T p.M3871I | Missense Mutation (SNP) | VAF 72/466 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT2 | c.11612T>A p.M3871K | Missense Mutation (SNP) | VAF 71/463 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT4 | c.8561G>T p.W2854L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FOXF2 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 21/409 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2
- GPR173 | c.847C>A p.Q283K | Missense Mutation (SNP) | VAF 103/545 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GREB1L | c.3277G>A p.D1093N | Missense Mutation (SNP) | VAF 158/897 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HELZ2 | c.7535C>T p.T2512I (on ENST00000467148 / NM_001037335.2; = p.T1943I on NM_033405.3) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- HTR2A | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 115/509 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- HTR7 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 195/472 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- IGKV6D-41 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 261/1328 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- IGSF23 | c.575G>T p.S192I | Missense Mutation (SNP) | VAF 176/658 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, varscan2
- IL1RAP | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 71/400 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- IQCH | c.1818T>A p.Y606* | Nonsense Mutation (SNP) | VAF 196/826 reads (24%) | called by muse, mutect2, varscan2
- IRAK3 | c.398C>G p.T133S | Missense Mutation (SNP) | VAF 197/421 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ITIH2 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 161/440 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ITIH2 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 162/440 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- KRTDAP | c.129C>T p.A43= | Splice Region (SNP) | VAF 83/578 reads (14%) | called by muse, mutect2, varscan2
- LAMA1 | c.1405G>T p.G469W | Missense Mutation (SNP) | VAF 131/643 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- LAMA2 | c.3097C>A p.P1033T | Missense Mutation (SNP) | VAF 156/875 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LINGO1 | c.1058C>A p.S353* | Nonsense Mutation (SNP) | VAF 185/342 reads (54%) | called by muse, mutect2, varscan2
- LPA | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 191/845 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEE2 | c.434_443del p.R145Ifs*9 | Frame Shift Del (DEL) | VAF 114/302 reads (38%) | called by mutect2, pindel, varscan2
- MAP7D2 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 299/551 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- MFSD6 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 90/641 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MORC2 | c.1726G>T p.E576* (on ENST00000397641 / NM_001303256.3; = p.E514* on NM_014941.3) | Nonsense Mutation (SNP) | VAF 73/263 reads (28%) | called by muse, mutect2, varscan2
- MRPS25 | c.68T>G p.F23C | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- MTMR14 | c.1102G>C p.V368L | Missense Mutation (SNP) | VAF 173/753 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- MUC17 | c.12596_12608del p.F4199* | Frame Shift Del (DEL) | VAF 61/269 reads (23%) | called by mutect2, pindel, varscan2
- MYBL1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 230/321 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- N4BP2 | c.3175A>G p.K1059E | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- NUDT17 | c.376+2T>G p.X126_splice | Splice Site (SNP) | VAF 95/328 reads (29%) | called by muse, mutect2, varscan2
- OFD1 | c.103dup p.T35Nfs*13 | Frame Shift Ins (INS) | VAF 566/1200 reads (47%) | called by mutect2, pindel, varscan2
- OPA3 | c.242C>A p.A81E | Missense Mutation (SNP) | VAF 58/270 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10X1 | c.791T>A p.V264D | Missense Mutation (SNP) | VAF 89/680 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PAK5 | c.1279G>T p.V427L | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2250G>T p.R750S (on ENST00000259318 / NM_001136562.3; = p.R981S on NM_007203.5) | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PCDH15 | c.1409A>C p.D470A | Missense Mutation (SNP) | VAF 302/821 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD1L1 | c.4034G>T p.W1345L | Missense Mutation (SNP) | VAF 110/380 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- POTEC | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 112/733 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); called by muse, mutect2
- PPP1R2B | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 157/749 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- PPP4R3C | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 36/547 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2
- QRFPR | c.946A>G p.I316V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.018); called by muse, mutect2
- RAI2 | c.747del p.I250Sfs*39 | Frame Shift Del (DEL) | VAF 27/57 reads (47%) | called by mutect2, pindel, varscan2
- RBM14 | c.452A>C p.Q151P | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- RGS12 | c.2427G>T p.Q809H | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- RYR2 | c.4945G>T p.E1649* | Nonsense Mutation (SNP) | VAF 26/232 reads (11%) | called by muse, varscan2
- SAMHD1 | c.937T>A p.W313R | Missense Mutation (SNP) | VAF 128/774 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SBSN | c.1140G>A p.W380* | Nonsense Mutation (SNP) | VAF 89/597 reads (15%) | called by muse, mutect2, varscan2
- SCN3A | c.4193T>C p.V1398A | Missense Mutation (SNP) | VAF 185/438 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SEMA6D | c.3028G>T p.D1010Y (on ENST00000316364 / NM_153618.2; = p.D948Y on NM_020858.2) | Missense Mutation (SNP) | VAF 120/256 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLFN14 | c.1552A>T p.T518S | Missense Mutation (SNP) | VAF 60/305 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SNX14 | c.1627G>T p.V543L (on ENST00000314673 / NM_001350535.1; = p.V490L on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/327 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- SPATA33 | c.34+7C>T | Splice Region (SNP) | VAF 46/120 reads (38%) | called by muse, varscan2
- SSUH2 | c.435G>T p.Q145H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- STAG3 | c.2534T>A p.V845D | Missense Mutation (SNP) | VAF 174/293 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SVEP1 | c.9801T>A p.C3267* | Nonsense Mutation (SNP) | VAF 48/206 reads (23%) | called by muse, mutect2, varscan2
- TCF24 | c.349T>A p.L117M | Missense Mutation (SNP) | VAF 87/145 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TDRD12 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 90/229 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIAM1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPST2 | c.565G>T p.V189L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- TRBV29-1 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 162/923 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- TRIM66 | c.1774A>G p.T592A | Missense Mutation (SNP) | VAF 100/281 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TSHZ3 | c.2516T>A p.L839Q | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- TTN | c.63829G>A p.A21277T (on ENST00000591111; = p.A13853T on NM_003319.4) | Missense Mutation (SNP) | VAF 44/342 reads (13%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UGT2B11 | c.1271A>C p.D424A | Missense Mutation (SNP) | VAF 141/484 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- WAPL | c.1894T>A p.L632I | Missense Mutation (SNP) | VAF 46/326 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- XRCC3 | c.644T>A p.V215E | Missense Mutation (SNP) | VAF 144/641 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZAN | c.4837C>A p.L1613M | Missense Mutation (SNP) | VAF 80/117 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ZBBX | c.1564T>C p.S522P | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); called by muse, varscan2
- ZFHX3 | c.10288G>A p.E3430K | Missense Mutation (SNP) | VAF 157/459 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZKSCAN8 | c.1671G>T p.Q557H | Missense Mutation (SNP) | VAF 33/331 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ZMYM4 | c.1073A>T p.K358I | Missense Mutation (SNP) | VAF 140/628 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF382 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 57/426 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF571 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 73/568 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2
- ZNF630 | c.1634G>T p.C545F | Missense Mutation (SNP) | VAF 129/270 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF69 | c.1255A>T p.K419* | Nonsense Mutation (SNP) | VAF 104/225 reads (46%) | called by muse, mutect2
- ZNF727 | c.1484T>A p.L495* | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | called by muse, mutect2, varscan2
- AKAP12 | c.4023C>T p.V1341= | Silent (SNP) | VAF 97/370 reads (26%) | catalogued as rs367742106; called by muse, mutect2, varscan2
- AMTN | c.429G>C p.G143= | Silent (SNP) | VAF 104/516 reads (20%) | called by muse, mutect2, varscan2
- AVPR1A | c.1005A>G p.L335= | Silent (SNP) | VAF 117/264 reads (44%) | catalogued as COSV54546013; called by muse, mutect2, varscan2
- BEND4 | c.357G>T p.P119= | Silent (SNP) | VAF 62/148 reads (42%) | called by muse, mutect2, varscan2
- C2CD4D | c.498T>G p.P166= | Silent (SNP) | VAF 10/74 reads (14%) | called by muse, varscan2
- CCT8L2 | c.573C>A p.I191= | Silent (SNP) | VAF 57/114 reads (50%) | catalogued as COSV100742569; called by muse, mutect2, varscan2
- COG3 | c.609G>A p.L203= | Silent (SNP) | VAF 104/536 reads (19%) | called by muse, mutect2, varscan2
- CSDE1 | c.1251G>T p.T417= (on ENST00000358528 / NM_001007553.3; = p.T386= on NM_007158.6) | Silent (SNP) | VAF 79/444 reads (18%) | catalogued as COSV99794493; called by muse, mutect2, varscan2
- DAG1 | c.855A>T p.A285= | Silent (SNP) | VAF 60/263 reads (23%) | catalogued as COSV100444746; called by muse, mutect2, varscan2
- DENND1B | c.909A>T p.L303= | Silent (SNP) | VAF 110/559 reads (20%) | called by muse, mutect2, varscan2
- DMTF1 | c.2097T>G p.V699= | Silent (SNP) | VAF 91/314 reads (29%) | called by muse, mutect2, varscan2
- EDEM3 | c.30G>T p.G10= | Silent (SNP) | VAF 84/291 reads (29%) | called by muse, mutect2, varscan2
- EFCAB5 | c.2946G>C p.L982= | Silent (SNP) | VAF 32/185 reads (17%) | called by muse, mutect2, varscan2
- FNDC3B | c.2190C>T p.V730= | Silent (SNP) | VAF 94/536 reads (18%) | catalogued as rs200807692, COSV61048489; called by muse, mutect2, varscan2
- IARS1 | c.552A>T p.A184= | Silent (SNP) | VAF 45/215 reads (21%) | called by muse, mutect2, varscan2
- IGKV3-11 | c.225C>G p.A75= | Silent (SNP) | VAF 264/1638 reads (16%) | called by muse, mutect2, varscan2
- IQCH | c.1719C>G p.A573= | Silent (SNP) | VAF 172/706 reads (24%) | called by muse, mutect2, varscan2
- LHFPL4 | c.720C>A p.P240= | Silent (SNP) | VAF 85/384 reads (22%) | catalogued as COSV99805645; called by muse, varscan2
- LILRA1 | c.408C>A p.T136= | Silent (SNP) | VAF 64/213 reads (30%) | catalogued as COSV52185270; called by muse, mutect2
- MORC2 | c.1725G>T p.L575= (on ENST00000397641 / NM_001303256.3; = p.L513= on NM_014941.3) | Silent (SNP) | VAF 74/267 reads (28%) | called by muse, mutect2, varscan2
- MUC4 | c.12885C>T p.P4295= (on ENST00000463781 / NM_018406.7; = p.P59= on NM_004532.6) | Silent (SNP) | VAF 34/205 reads (17%) | called by muse, mutect2, varscan2
- NRXN3 | c.1590G>T p.V530= (on ENST00000335750 / NM_001330195.2; = p.V157= on NM_004796.6) | Silent (SNP) | VAF 79/429 reads (18%) | catalogued as COSV100208252, COSV59795661; called by muse, mutect2, varscan2
- NUPR2 | c.252C>A p.R84= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as COSV100253714, COSV61409435; called by muse, mutect2, varscan2
- OTULINL | c.234A>T p.G78= | Silent (SNP) | VAF 73/220 reads (33%) | called by muse, mutect2, varscan2
- PIK3C2G | c.1413A>T p.S471= | Silent (SNP) | VAF 50/345 reads (14%) | called by muse, mutect2, varscan2
- SALL1 | c.3945G>T p.V1315= | Silent (SNP) | VAF 182/484 reads (38%) | called by muse, mutect2, varscan2
- SLC30A3 | c.681G>A p.L227= | Silent (SNP) | VAF 133/576 reads (23%) | called by muse, mutect2, varscan2
- SOAT2 | c.1491C>T p.Y497= | Silent (SNP) | VAF 62/312 reads (20%) | catalogued as rs139333372; called by muse, mutect2, varscan2
- SOX30 | c.1851C>T p.F617= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.2928A>C p.T976= | Silent (SNP) | VAF 69/287 reads (24%) | catalogued as COSV61193650; called by muse, mutect2, varscan2
- ST14 | c.2475C>T p.S825= | Silent (SNP) | VAF 78/242 reads (32%) | catalogued as rs61737059; called by muse, varscan2
- TBCC | c.810C>T p.R270= | Silent (SNP) | VAF 187/386 reads (48%) | called by muse, mutect2, varscan2
- TGDS | c.366T>C p.T122= | Silent (SNP) | VAF 163/473 reads (34%) | called by muse, mutect2, varscan2
- TNNI3 | c.474G>C p.L158= | Silent (SNP) | VAF 85/361 reads (24%) | catalogued as rs749880457; ClinVar: likely benign; called by muse, mutect2, varscan2
- USH2A | c.12858C>T p.I4286= | Silent (SNP) | VAF 228/1020 reads (22%) | catalogued as COSV56351925; called by muse, mutect2, varscan2
- WDR87 | c.3711A>T p.G1237= | Silent (SNP) | VAF 50/279 reads (18%) | called by muse, mutect2, varscan2
- ZNF69 | c.1257G>A p.K419= | Silent (SNP) | VAF 98/220 reads (45%) | called by muse, mutect2
- ANXA8 | c.*2G>A | 3'UTR (SNP) | VAF 113/816 reads (14%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29701599 G>A | 3'Flank (SNP) | VAF 330/1447 reads (23%) | catalogued as rs756956467; called by muse, mutect2, varscan2
- CALCA | chr11:14967783 C>A | 3'Flank (SNP) | VAF 150/817 reads (18%) | called by muse, mutect2, varscan2
- CES5A | c.-1G>T | 5'UTR (SNP) | VAF 78/384 reads (20%) | called by muse, mutect2, varscan2
- CSMD2 | c.8312-7396C>A | Intron (SNP) | VAF 32/153 reads (21%) | called by muse, mutect2
- CYP2A7P1 | n.653T>A | RNA (SNP) | VAF 38/203 reads (19%) | called by muse, mutect2, varscan2
- DNER | c.-9C>T | 5'UTR (SNP) | VAF 3/17 reads (18%) | catalogued as rs1481683377; called by muse, varscan2
- IFT140 | c.*25T>A | 3'UTR (SNP) | VAF 59/184 reads (32%) | catalogued as COSV51980315; called by muse, mutect2, varscan2
- KIF13A | c.146+35629G>A | Intron (SNP) | VAF 19/413 reads (5%) | called by muse, mutect2
- MATR3 | c.*1256C>T | 3'UTR (SNP) | VAF 89/493 reads (18%) | called by muse, mutect2, varscan2
- MMS19 | c.262+686C>T | Intron (SNP) | VAF 89/526 reads (17%) | called by muse, mutect2, varscan2
- NUDT14 | c.126-234dup | Intron (INS) | VAF 10/32 reads (31%) | catalogued as rs1452069471; called by mutect2, pindel, varscan2
- OR51A4 | chr11:4943514 T>A | 3'Flank (SNP) | VAF 33/154 reads (21%) | called by muse, mutect2, varscan2
- PACRG | c.613+101553G>C | Intron (SNP) | VAF 154/617 reads (25%) | called by muse, mutect2, varscan2
- PIK3R2 | c.1417-49G>T | Intron (SNP) | VAF 119/753 reads (16%) | called by muse, mutect2, varscan2
- PIP5K1A | c.*67G>T | 3'UTR (SNP) | VAF 100/977 reads (10%) | called by muse, mutect2, varscan2
- PKD1 | c.7210-26C>T | Intron (SNP) | VAF 62/201 reads (31%) | catalogued as rs779375051; called by muse, mutect2, varscan2
- POU2F2 | c.1401-156del | Intron (DEL) | VAF 38/351 reads (11%) | called by mutect2, pindel, varscan2
- PTGDS | c.331+146G>T | Intron (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- RAD51D | c.-88G>T | 5'UTR (SNP) | VAF 39/155 reads (25%) | called by muse, mutect2, varscan2
- RDX | c.13-416A>T | Intron (SNP) | VAF 204/389 reads (52%) | called by muse, mutect2, varscan2
- RGS3 | c.416-13G>A | Intron (SNP) | VAF 72/276 reads (26%) | called by muse, mutect2, varscan2
- SENP6 | c.147-1131G>T | Intron (SNP) | VAF 67/368 reads (18%) | called by muse, mutect2, varscan2
- SHROOM3 | c.3753+45C>A | Intron (SNP) | VAF 60/293 reads (20%) | called by muse, mutect2, varscan2
- SRGAP1 | c.1408+22G>T | Intron (SNP) | VAF 195/1144 reads (17%) | called by muse, mutect2, varscan2
- TLCD3A | c.122+158del | Intron (DEL) | VAF 4/22 reads (18%) | called by pindel, varscan2
- UFD1 | c.-18T>A | 5'UTR (SNP) | VAF 76/350 reads (22%) | catalogued as rs764224483; called by muse, mutect2, varscan2
- VAPB | c.*671G>A | 3'UTR (SNP) | VAF 214/1299 reads (16%) | called by muse, mutect2, varscan2
